Gene-level copy-number profile of tumor specimen TCGA-BT-A3PJ-01A from TCGA case TCGA-BT-A3PJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 76.2 years (27,821 days).
Specimen TCGA-BT-A3PJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.0c50f81c-a071-4690-a25b-56a27daebebe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BT-A3PJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/34010221-338d-4d29-88eb-d3dd943e17fc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 12; copy number 2: 9,447; copy number 3: 27,429; copy number 4: 14,635; copy number 5: 4,279; copy number 6: 1,583; copy number 7: 846; copy number 8: 719; copy number 9: 376; copy number 10: 157; copy number 11: 13; copy number 13: 11; copy number 14: 27; copy number 15: 18; copy number 19: 49; copy number 20: 57; copy number 26: 113; copy number 48: 4; copy number 56: 30; copy number 59: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A3PJ-01A-21D-A21Y-01): tumor purity 0.51, ploidy 3.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,426 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,062,484–167,708,696, 255 genes, copy number 8–26 (within-gene range 2–26) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 8–9 (broad region; genes not listed).
- chr6:1,601,654–4,130,951, 61 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr6:11,414,636–22,654,455, 147 genes, copy number 8–14 (within-gene range 3–14) (broad region; genes not listed).
- chr6:63,193,072–63,779,336, 16 genes, copy number 15: AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,822,642, 2 genes, copy number 15: AL354719.1, SCAT8.
- chr7:46,144,937–48,647,497, 26 genes, copy number 7 (within-gene range 5–7): ZNF619P1, AC023669.1, AC023669.2, AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13.
- chr7:52,269,437–55,260,256, 36 genes, copy number 11–56: AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr7:56,214,979–56,340,337, 6 genes, copy number 59: AC006970.2, CCNJP1, AC073136.1, AC073136.2, AC093392.1, RNU6-1335P.
- chr8:81,149,107–94,475,115, 190 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr9:14,475–10,612,723, 147 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr9:10,532,145–43,045,120, 628 genes, copy number 7 (broad region; genes not listed).
- chr13:68,985,058–70,459,570, 10 genes, copy number 8: ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1, KLHL1, RNY3P10, PSMC1P13, ATXN8OS, AL160391.1, RNU6-54P.
- chr20:42,072,752–48,827,999, 192 genes, copy number 8–20 (within-gene range 3–37) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
